Somatic mutation profile of tumor specimen TCGA-C5-A7CH-01A (aliquot TCGA-C5-A7CH-01A-11D-A33O-09) from TCGA case TCGA-C5-A7CH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.2 years (15,777 days).
Specimen TCGA-C5-A7CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce15ec0e-5962-44ef-8939-c85f72fcd45f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7CH-10A (Blood Derived Normal), aliquot TCGA-C5-A7CH-10A-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dee801c-d3f3-426e-a3c1-357c1bbbed6a

The open-access MAF lists 66 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK2 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV50781304, COSV99301305; called by muse, mutect2, varscan2
- ALAS2 | c.507C>A p.N169K | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58190108; called by muse, mutect2, varscan2
- ALLC | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52994347; called by muse, mutect2
- ATG101 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as COSV61084810, COSV61085151; called by muse, mutect2, varscan2
- C7orf31 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as rs776399566, COSV52217125, COSV52220311; called by muse, mutect2, varscan2
- CHRNA5 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs1376188067, COSV55138456; called by muse, mutect2, varscan2
- CNTNAP5 | c.3774G>A p.M1258I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.462); catalogued as rs1218243400, COSV70484278, COSV70513313; called by muse, mutect2, varscan2
- COCH | c.1447G>C p.E483Q (on ENST00000216361 / NM_001347720.1; = p.E418Q on NM_004086.3) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53550721, COSV53550761; called by muse, mutect2, varscan2
- COPS2 | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV54644325; called by muse, mutect2, varscan2
- CRISP1 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.294); catalogued as COSV59993483; called by muse, mutect2, varscan2
- CSMD1 | c.9863G>C p.R3288T (on ENST00000520002; = p.R3287T on NM_033225.6) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.985); catalogued as rs1255291067, COSV59317509, COSV59380457; called by muse, mutect2, varscan2
- CSMD1 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68200247; called by muse, mutect2, varscan2
- DCX | c.932G>A p.G311D (on ENST00000636035 / NM_001195553.2; = p.X311_splice on NM_000555.3) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57568945, COSV57574514; called by muse, mutect2, varscan2
- DENND5B | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV60902275; called by muse, mutect2, varscan2
- EIPR1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs376448610; called by muse, mutect2, varscan2
- ENO1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52303691; called by muse, mutect2, varscan2
- GABRG2 | c.1186T>A p.L396M (on ENST00000361925 / NM_001375343.1; = p.L356M on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62717688; called by muse, mutect2, varscan2
- GPC6 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100990201, COSV65509540; called by muse, mutect2, varscan2
- HMCN1 | c.824A>C p.H275P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs368798833; called by muse, mutect2, varscan2
- IRGQ | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs150440122; called by mutect2, varscan2
- ITIH6 | c.35T>A p.F12Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV54488659; called by muse, mutect2, varscan2
- KDM3A | c.2423del p.G808Afs*3 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as COSV57220255; called by mutect2, pindel, varscan2
- KLF3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs183262895, COSV99789723; called by muse, mutect2, varscan2
- KMT2C | c.12340G>A p.E4114K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51419906; called by muse, mutect2, varscan2
- LRP2 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772364125, COSV55551512; called by muse, mutect2, varscan2
- MFSD6L | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV61002890; called by muse, mutect2, varscan2
- MS4A14 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV55734635; called by muse, mutect2, varscan2
- MYOM2 | c.3594C>G p.Y1198* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100037329; called by muse, mutect2
- OGT | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65480651, COSV65481755; called by muse, mutect2, varscan2
- ONECUT2 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771314671, COSV72153080; called by muse, mutect2, varscan2
- PCIF1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65026378; called by muse, mutect2
- PRKACA | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58067791; called by muse, mutect2, varscan2
- RAB34 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.84); catalogued as rs757773764, COSV56386477; called by muse, mutect2, varscan2
- ROR2 | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV65218657; called by muse, mutect2, varscan2
- SCUBE3 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51456592; called by muse, mutect2, varscan2
- SEC24C | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747788825, COSV59541603; called by muse, mutect2, varscan2
- SIGLEC10 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59481224; called by muse, mutect2, varscan2
- SLC12A6 | c.2944G>A p.D982N (on ENST00000354181 / NM_001365088.1; = p.D931N on NM_005135.2) | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51625670; called by muse, mutect2, varscan2
- SMARCA4 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60793288, COSV60812414; called by muse, mutect2, varscan2
- SPTA1 | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV63752423, COSV63761847; called by muse, mutect2, varscan2
- STAG1 | c.1025G>T p.R342M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs143925042, COSV52608221; called by muse, mutect2, varscan2
- SYNPO | c.1477G>T p.G493W (on ENST00000394243 / NM_001166208.2; = p.G249W on NM_007286.6) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56939890; called by muse, mutect2, varscan2
- TMEM115 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51704661; called by muse, mutect2, varscan2
- TMIGD3 | c.569C>G p.S190* (on ENST00000369717 / NM_001081976.2; = p.S271* on NM_020683.7) | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV63163295, COSV63163453, COSV63163628; called by muse, mutect2, varscan2
- TNS3 | c.1979C>G p.S660C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60790461; called by muse, mutect2, varscan2
- XIRP2 | c.1399A>G p.K467E (on ENST00000628543; = p.K642E on NM_152381.6) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV54697345; called by muse, mutect2
- ZBTB40 | c.3244G>C p.E1082Q | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV65145203; called by muse, mutect2, varscan2
- ZMYM3 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1174153455, COSV58737637; called by muse, mutect2, varscan2
- ZNF398 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60064370, COSV60064487; called by muse, mutect2, varscan2
- ZNF486 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58718825; called by muse, mutect2, varscan2
- PIP4P2 | c.312del p.L105Sfs*10 | Frame Shift Del (DEL) | VAF 68/125 reads (54%) | called by mutect2, pindel, varscan2
- SPANXN2 | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CACNA1C | c.5283C>T p.T1761= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs747358417, COSV59712836; ClinVar: likely benign; called by muse, mutect2, varscan2
- ETS1 | c.385C>T p.L129= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV60093266; called by muse, mutect2, varscan2
- GRIP2 | c.2583G>A p.L861= (on ENST00000619221; = p.L764= on NM_001080423.4) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56121147; called by muse, mutect2, varscan2
- GRXCR1 | c.522C>T p.N174= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV67671573; called by muse, mutect2, varscan2
- IP6K3 | c.885G>A p.R295= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53390103; called by muse, mutect2, varscan2
- KNDC1 | c.3315C>T p.A1105= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58836236; called by muse, mutect2, varscan2
- OR10AG1 | c.303G>A p.T101= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs774639849, COSV56631456; called by muse, mutect2, varscan2
- PHF21A | c.501T>C p.A167= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV57653198; called by muse, mutect2, varscan2
- POLR3C | c.1563C>T p.F521= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57907212; called by muse, mutect2, varscan2
- RYR1 | c.2041T>C p.L681= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1405685696, COSV62096129; called by muse, mutect2
- WWC3 | c.594T>A p.P198= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- ZDBF2 | c.588C>T p.N196= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs538759150, COSV65625287; called by muse, mutect2, varscan2
- AP000769.3 | n.49_51dup | RNA (INS) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- ESRRB | c.1296+316G>A | Intron (SNP) | VAF 8/122 reads (7%) | catalogued as COSV99835129; called by muse, mutect2
